Surgical pathology report (de-identified scan), TCGA case TCGA-5L-AAT1, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site University of Sao Paulo, specimen TCGA-5L-AAT1-01A (Primary Tumor).

ICD O-3

Carcinoma, lobular infiltrating
NOS 8520/3

Site: R Breast NOS C50.9

W 5/21/14

Date:
Gender: Female
Color: White
Origin:
Nature of material: Breast
Biopsy number:

PATHOLOGY REPORT:

Gross description:

Specimens are received in three containers.

Container 01: Right breast (mastectomy) weighing 863 g. It measures 22.5 x 17.5 x 4.0 cm. Superficially, a skin ellipse is seen, and measures 18.0 x 7.0 cm. There is no superficial lesion. On slicing in the breast parenchyma is a white spiculated nodule with central necrosis measuring 3.5 x 2.5 x 0.8 cm. Macroscopically, all the margins are clear.

Container 02: Axillary lymph node: One white, soft and nodular tissue measuring 1.1 x 0.8 x 0.3 cm containing no gross lesion.

Container 03: 10 Axillary lymph nodes. A gross nodular fibrofatty tissue measuring 3.0 x 2.2 x 0.6 cm in aggregate. Contained within the tissue are 4 soft nodular structures with diameters ranging from 0.2 to 0.4 cm in the largest diameters.

Microscopy
Dispensable description.

Conclusions:

Right breast:

- Invasive lobular carcinoma, grade 1, measuring 1.1 cm in the largest diameter;
- Clear surgical margins.

Lymph nodes:

- There is no lymph nodes metastasis.

PARTICIPANTS OF APPRAISAL REPORT

- Issuer

Source: NCI Genomic Data Commons file 0b886d14-3ca9-42b8-afb5-e989fc73ec5c (TCGA-5L-AAT1.B5CA42BB-9514-42C6-9FB0-C8889C1DC51A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).